MMRF case MMRF_2126 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/62c565fb-13c2-479d-871c-697d4db8cb72

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 70 years; Vital status: Dead; Days to death: 566 days (1.5 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 71.0 years (25,948 days); ISS stage: II; Days to last known disease status: 566 days (1.5 years); Days to last follow up: 566 days (1.5 years).
   Treatment given: Therapeutic agents: Bortezomib + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 36 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 249 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 92 days; Days to treatment end: 117 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 134 days; Days to treatment end: 246 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 330 days; Days to treatment end: 543 days (1.5 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 330 days; Days to treatment end: 551 days (1.5 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 566.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -32 (ECOG 1): M Protein 3.47 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.595 mg/dL; Immunoglobulin G 45.5 g/L; Immunoglobulin A 0.13 g/L; Immunoglobulin M 0.16 g/L; Hemoglobin 7.5 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 53 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.28 mmol/L; Albumin 37 g/L; Total Protein 8.6 g/dL; Glucose 13.1 mmol/L.
- Day 47 (ECOG 0): M Protein 2.92 g/dL; Immunoglobulin G 40.1 g/L; Immunoglobulin A 0.16 g/L; Immunoglobulin M 0.55 g/L; Hemoglobin 7.19 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 29 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.28 mmol/L; Albumin 33 g/L; Total Protein 8.2 g/dL; Glucose 12.6 mmol/L.
- Day 155 (ECOG 1): M Protein 1.5 g/dL; Immunoglobulin G 25.2 g/L; Immunoglobulin A 0.22 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 3.16 µg/mL; Lactate Dehydrogenase 2.7 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 42 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.2 mmol/L; Albumin 35 g/L; Total Protein 7.6 g/dL; Glucose 12.9 mmol/L.
- Day 256 (ECOG 2): M Protein 1.98 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.96 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.487 mg/dL; Immunoglobulin G 25.9 g/L; Immunoglobulin A 0.21 g/L; Immunoglobulin M 0.24 g/L; Beta 2 Microglobulin 3.68 µg/mL; Hemoglobin 7.07 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 66 ×10⁹/L; Creatinine 108 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.2 mmol/L; Albumin 34 g/L; Total Protein 7.2 g/dL; Glucose 6.27 mmol/L.
- Day 347 (ECOG 2): M Protein 2.46 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.72 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.52 mg/dL; Immunoglobulin G 30.7 g/L; Immunoglobulin A 0.14 g/L; Immunoglobulin M 0.29 g/L; Beta 2 Microglobulin 3.4 µg/mL; Lactate Dehydrogenase 2.7 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 57 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 8 g/dL; Glucose 6.44 mmol/L.
- Day 400 (ECOG 2): M Protein 1.75 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.92 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.32 mg/dL; Immunoglobulin G 23.3 g/L; Immunoglobulin A 0.57 g/L; Immunoglobulin M 0.41 g/L; Beta 2 Microglobulin 3.6 µg/mL; Lactate Dehydrogenase 2.77 µkat/L; Hemoglobin 5.95 mmol/L; Leukocytes 2.5 ×10⁹/L; Absolute Neutrophil 0.8 ×10⁹/L; Platelets 64 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.08 mmol/L; Albumin 33 g/L; Total Protein 7.1 g/dL; Glucose 8.2 mmol/L.
- Day 521 (ECOG 2): M Protein 2.36 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.14 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.06 mg/dL; Immunoglobulin G 26.8 g/L; Immunoglobulin A 0.42 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 4.5 µg/mL; Lactate Dehydrogenase 2.4 µkat/L; Hemoglobin 5.95 mmol/L; Leukocytes 2.78 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 41 ×10⁹/L; Creatinine 91.1 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 1.98 mmol/L; Albumin 28 g/L; Total Protein 6.9 g/dL; Glucose 10.3 mmol/L.
- Day 551 (ECOG 2): Hemoglobin 4.96 mmol/L; Leukocytes 5.07 ×10⁹/L; Absolute Neutrophil 3.35 ×10⁹/L; Platelets 56 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2 mmol/L; Albumin 14 g/L; Total Protein 9.7 g/dL; Glucose 6.11 mmol/L.

Other clinical attributes
- Day -32: Weight: 105 kg; Height: 160 cm.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples)
- Sample MMRF_2126_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -32 days.
- Sample MMRF_2126_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -32 days.
- Sample MMRF_2126_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 521 days (1.4 years).
